Somatic mutation profile of tumor specimen cdcc4b54-fcf8-4667-a686-9abda4 (aliquot cdcc4b54-fcf8-4667-a686-9abda4_D6_1) from CPTAC case 22BR006, project CPTAC-2 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 54.5 years (19,922 days).
Specimen cdcc4b54-fcf8-4667-a686-9abda4: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d642dca8-16a2-4d99-ba76-b034660633a7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 4d08772f-7a24-4de1-b997-60dd02 (Blood Derived Normal), aliquot 4d08772f-7a24-4de1-b997-60dd02_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5f3cdd1a-0d7e-4a85-9ae2-f4d6e1cbf621

The open-access MAF lists 25 somatic variants for this specimen: 18 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 5, Frame Shift Del 3, Splice Site 2, Nonsense Mutation 2, 5'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASXL1 | c.1723C>T p.Q575* | Nonsense Mutation (SNP) | VAF 33/241 reads (14%) | hotspot (GDC flag); catalogued as rs747847938, COSV60114701; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 73/206 reads (35%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- DAPK1 | c.3277C>T p.R1093W | Missense Mutation (SNP) | VAF 17/142 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs773488770, COSV63790779; called by muse, mutect2, varscan2
- DCBLD1 | c.1996G>A p.D666N | Missense Mutation (SNP) | VAF 41/252 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1181971894, COSV99757030; called by muse, mutect2, varscan2
- GATA3 | c.922-3_922-2del p.X308_splice | Splice Site (DEL) | VAF 35/160 reads (22%) | catalogued as rs763236375, COSV60515023; called by mutect2, pindel, varscan2
- KMT2C | c.5082+2T>C p.X1694_splice | Splice Site (SNP) | VAF 53/169 reads (31%) | catalogued as COSV51419865; called by muse, mutect2, varscan2
- PCDHB1 | c.128C>T p.S43L | Missense Mutation (SNP) | VAF 14/374 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as rs900032895; called by muse, mutect2
- SYTL5 | c.772C>G p.P258A | Missense Mutation (SNP) | VAF 23/122 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.045); catalogued as COSV52902164; called by muse, mutect2, varscan2
- TNRC18 | c.8812T>C p.Y2938H | Missense Mutation (SNP) | VAF 29/200 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.103); catalogued as COSV99786848; called by muse, mutect2, varscan2
- BMPR1A | c.831C>G p.I277M | Missense Mutation (SNP) | VAF 76/392 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CBFB | c.387_388del p.E130Afs*14 | Frame Shift Del (DEL) | VAF 6/33 reads (18%) | called by mutect2, pindel, varscan2
- DCLK3 | c.1714T>A p.F572I | Missense Mutation (SNP) | VAF 54/173 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.792); called by muse, mutect2, varscan2
- DNAAF1 | c.702C>A p.D234E | Missense Mutation (SNP) | VAF 17/342 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); called by muse, mutect2
- FKTN | c.753G>T p.R251S | Missense Mutation (SNP) | VAF 17/343 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.031); called by muse, mutect2
- MUC5B | c.9037T>G p.S3013A | Missense Mutation (SNP) | VAF 27/140 reads (19%) | SIFT tolerated (0.5); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- WWP1 | c.2435G>A p.W812* | Nonsense Mutation (SNP) | VAF 32/158 reads (20%) | called by muse, mutect2, varscan2
- ZNF652 | c.1702_1715del p.P568Tfs*6 | Frame Shift Del (DEL) | VAF 9/48 reads (19%) | called by mutect2, pindel
- ZNF746 | c.1214del p.P405Rfs*36 | Frame Shift Del (DEL) | VAF 15/129 reads (12%) | called by mutect2, pindel, varscan2
- GALK1 | c.864G>A p.T288= | Silent (SNP) | VAF 33/156 reads (21%) | catalogued as rs201247556, COSV52324098; called by muse, mutect2, varscan2
- KCNH1 | c.768C>T p.I256= | Silent (SNP) | VAF 46/440 reads (10%) | catalogued as rs764963478; called by muse, mutect2
- OR9A2 | c.768G>A p.V256= | Silent (SNP) | VAF 33/178 reads (19%) | called by muse, mutect2, varscan2
- RBM22 | c.552G>A p.E184= | Silent (SNP) | VAF 17/132 reads (13%) | called by muse, mutect2, varscan2
- VANGL1 | c.663A>G p.Q221= | Silent (SNP) | VAF 65/228 reads (29%) | catalogued as rs779577966; called by muse, mutect2, varscan2
- GRHPR | c.287+47T>C | Intron (SNP) | VAF 20/81 reads (25%) | called by muse, mutect2, varscan2
- GTF2B | c.-17C>T | 5'UTR (SNP) | VAF 17/106 reads (16%) | catalogued as rs777123874; called by muse, mutect2, varscan2
